Somatic mutation profile of tumor specimen TCGA-76-6657-01A (aliquot TCGA-76-6657-01A-11D-1845-08) from TCGA case TCGA-76-6657, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 74.9 years (27,341 days).
Specimen TCGA-76-6657-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3de73bea-9c6f-4974-b7dc-f3148ea00945.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-76-6657-10A (Blood Derived Normal), aliquot TCGA-76-6657-10A-01D-1845-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d2eece18-dbed-49d3-b855-f7201e716e2f

The open-access MAF lists 57 somatic variants for this specimen: 44 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 12, Frame Shift Del 3, Splice Site 3, In Frame Del 2, Frame Shift Ins 2, Nonsense Mutation 2, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.2850+1G>A p.X950_splice | Splice Site (SNP) | VAF 30/83 reads (36%) | catalogued as rs1131691122, CS031788, CS086413, COSV62196412; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACACB | c.5713G>A p.V1905M | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.294); catalogued as rs182648370; called by muse, mutect2, varscan2
- ADGRV1 | c.7967T>C p.I2656T | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV67988132; called by muse, mutect2, varscan2
- ALX1 | c.934C>T p.R312* | Nonsense Mutation (SNP) | VAF 30/84 reads (36%) | catalogued as COSV57492828; called by muse, mutect2, varscan2
- ARAP3 | c.2282G>A p.G761E | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.63); catalogued as rs377450993, COSV53351594, COSV53351839; called by muse, mutect2, varscan2
- BLM | c.3357G>A p.L1119= | Splice Region (SNP) | VAF 34/108 reads (31%) | catalogued as rs1295137195, COSV61925012, COSV61925813; called by muse, mutect2, varscan2
- CACNA2D1 | c.1934C>T p.S645L (on ENST00000356253 / NM_001366867.1; = p.S633L on NM_000722.4) | Missense Mutation (SNP) | VAF 45/181 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.175); catalogued as rs149510838; called by muse, mutect2, varscan2
- CASP1 | c.934G>T p.E312* (on ENST00000436863 / NM_033292.4; = p.E291* on NM_001223.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 17/48 reads (35%) | catalogued as COSV62056899; called by muse, mutect2, varscan2
- CDH5 | c.1498A>C p.I500L | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.267); catalogued as COSV58518168; called by muse, mutect2
- CSK | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV54974370; called by muse, mutect2, varscan2
- CYP2C8 | c.343A>C p.S115R | Missense Mutation (SNP) | VAF 35/59 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64877719; called by muse, mutect2, varscan2
- DNMT3B | c.1058C>T p.T353M | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.224); catalogued as rs763492333, COSV52417220; called by muse, mutect2, varscan2
- DUSP5 | c.769G>A p.G257S | Missense Mutation (SNP) | VAF 21/32 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs373903086; called by muse, mutect2, varscan2
- DYRK4 | c.608G>A p.S203N | Missense Mutation (SNP) | VAF 41/155 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV50540733; called by muse, mutect2, varscan2
- EPPK1 | c.6504C>A p.S2168R | Missense Mutation (SNP) | VAF 100/274 reads (36%) | SIFT tolerated (0.59); PolyPhen benign (0.159); catalogued as COSV101599703, COSV73261577; called by muse, mutect2, varscan2
- FBN3 | c.3296C>T p.P1099L | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV54464185; called by muse, mutect2, varscan2
- FCER2 | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs773330209, COSV60915899, COSV60916700; called by muse, mutect2, varscan2
- FGA | c.898T>A p.S300T | Missense Mutation (SNP) | VAF 42/122 reads (34%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as COSV57397478; called by muse, mutect2, varscan2
- FYN | c.1087A>G p.K363E | Missense Mutation (SNP) | VAF 65/174 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.065); catalogued as COSV57616310; called by muse, mutect2, varscan2
- GCN1 | c.5315C>T p.T1772I | Missense Mutation (SNP) | VAF 53/132 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.057); catalogued as rs868459100, COSV56109763; called by muse, mutect2, varscan2
- HABP2 | c.862C>A p.P288T | Missense Mutation (SNP) | VAF 54/80 reads (68%) | SIFT tolerated (0.2); PolyPhen benign (0.021); catalogued as COSV63637139; called by muse, mutect2, varscan2
- HDAC8 | c.111+1G>A p.X37_splice | Splice Site (SNP) | VAF 38/54 reads (70%) | catalogued as COSV101002339; called by muse, mutect2, varscan2
- KHDC3L | c.422G>A p.R141Q | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.164); catalogued as rs1455756972, COSV64863075; called by muse, mutect2, varscan2
- LCE1F | c.247C>T p.R83C | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.656); catalogued as rs757077831, COSV57669423, COSV57670236; called by muse, mutect2, varscan2
- LZTR1 | c.428A>C p.N143T | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53148582; called by muse, mutect2, varscan2
- MACF1 | c.2403C>G p.F801L | Missense Mutation (SNP) | VAF 46/107 reads (43%) | catalogued as COSV58381107; called by muse, mutect2, varscan2
- MEF2A | c.829C>G p.P277A (on ENST00000557942 / NM_001319206.2; = p.P279A on NM_005587.4 and 8 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as rs373219260, COSV57534824; called by muse, mutect2, varscan2
- MISP | c.530G>A p.R177Q | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs377309090, COSV53121041; called by muse, mutect2
- OR5B3 | c.533A>T p.D178V | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV58677859; called by muse, mutect2, varscan2
- OR8D1 | c.821C>T p.S274F | Missense Mutation (SNP) | VAF 50/115 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs779518083, COSV63442557; called by muse, mutect2, varscan2
- PCID2 | c.821A>T p.Y274F | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.456); catalogued as COSV55814132; called by muse, mutect2, varscan2
- SCN3A | c.4337T>C p.L1446S | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as COSV51814023; called by muse, mutect2, varscan2
- TRBC2 | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782461606; called by muse, mutect2, varscan2
- UGT2A1 | c.1502C>T p.T501M | Missense Mutation (SNP) | VAF 49/143 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.058); catalogued as rs184187801, COSV54143007; called by muse, mutect2, varscan2
- ZC3H13 | c.2356C>T p.R786C | Missense Mutation (SNP) | VAF 82/229 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.818); catalogued as rs763446472, COSV54456741; called by muse, mutect2, varscan2
- KRT23 | c.799-19_799delinsTG p.X267_splice | Splice Site (DEL) | VAF 64/161 reads (40%) | called by pindel, varscan2*
- MSH6 | c.618_620del p.E207del | In Frame Del (DEL) | VAF 9/34 reads (26%) | called by pindel, varscan2
- NF1 | c.7729del p.Y2577Mfs*47 (on ENST00000358273 / NM_001042492.3; = p.Y2556Mfs*47 on NM_000267.3) | Frame Shift Del (DEL) | VAF 16/50 reads (32%) | called by mutect2, pindel, varscan2
- OR8B4 | c.329_331del p.E110_C111delinsG | In Frame Del (DEL) | VAF 24/69 reads (35%) | called by mutect2, pindel, varscan2
- PIK3R1 | c.244dup p.I82Nfs*24 | Frame Shift Ins (INS) | VAF 18/64 reads (28%) | called by mutect2, varscan2
- PTEN | c.339_343del p.S113Rfs*2 | Frame Shift Del (DEL) | VAF 37/66 reads (56%) | called by mutect2, pindel, varscan2
- RAB11FIP4 | c.1120_1121del p.Q374Afs*7 | Frame Shift Del (DEL) | VAF 7/23 reads (30%) | called by pindel, varscan2
- SPATA31A3 | c.2777C>T p.P926L | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); called by mutect2, varscan2
- UBR5 | c.1352dup p.L451Ffs*7 | Frame Shift Ins (INS) | VAF 16/61 reads (26%) | called by mutect2, pindel, varscan2
- ACSM2A | c.1539G>A p.S513= (on ENST00000219054; = p.S434= on NM_001308169.2) | Silent (SNP) | VAF 68/167 reads (41%) | catalogued as rs201744736; called by muse, mutect2, varscan2
- ALPK3 | c.546C>T p.F182= | Silent (SNP) | VAF 27/79 reads (34%) | catalogued as COSV51934970, COSV51936231; called by muse, mutect2, varscan2
- CHD5 | c.1029G>A p.Q343= | Silent (SNP) | VAF 23/39 reads (59%) | catalogued as COSV52417700; called by muse, mutect2, varscan2
- CNKSR3 | c.36G>A p.V12= | Silent (SNP) | VAF 41/121 reads (34%) | catalogued as COSV74155585; called by muse, mutect2, varscan2
- CTHRC1 | c.213C>T p.A71= | Silent (SNP) | VAF 48/168 reads (29%) | catalogued as rs1275648002, COSV57715799; called by muse, mutect2, varscan2
- DNAH5 | c.2868C>T p.R956= | Silent (SNP) | VAF 27/91 reads (30%) | catalogued as rs767246326, COSV54204914; called by muse, mutect2, varscan2
- EPS8L3 | c.1671C>T p.S557= (on ENST00000361965 / NM_133181.4; = p.S527= on NM_024526.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV62609015; called by muse, mutect2, varscan2
- OR10X1 | c.432C>T p.N144= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as COSV63767202, COSV63767527; called by muse, mutect2
- OR2T3 | c.324C>T p.F108= | Silent (SNP) | VAF 30/126 reads (24%) | catalogued as rs758551745, COSV62082744; called by muse, mutect2, varscan2
- POTED | c.216C>T p.C72= | Silent (SNP) | VAF 36/73 reads (49%) | catalogued as COSV100202964; called by muse, mutect2, varscan2
- RASAL2 | c.2205A>T p.G735= | Silent (SNP) | VAF 27/68 reads (40%) | catalogued as COSV62716237; called by muse, mutect2, varscan2
- SUMF2 | c.636C>T p.T212= (on ENST00000652303; = p.T193= on NM_015411.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/102 reads (25%) | catalogued as COSV51916927; called by muse, mutect2, varscan2
- MIR376A2 | n.69G>A | RNA (SNP) | VAF 19/89 reads (21%) | catalogued as rs780675569; called by muse, mutect2, varscan2
